Somatic mutation profile of tumor specimen BA2049D (aliquot aq-BA2049D) from BEATAML1.0 case 2189, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 42.7 years (15,585 days).
Specimen BA2049D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a147c9e-d3b6-4970-b8cb-4555b728a4fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2608D (Solid Tissue Normal), aliquot aq-BA2608D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3c1ae44-7a63-4f5a-a175-8d059aae07df

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GPRIN2 | c.298A>C p.T100P | Missense Mutation (SNP) | VAF 10/36 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs7090312; called by muse, mutect2
- CLNK | c.169G>T p.V57F | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.246); catalogued as COSV57020198; called by muse, mutect2
- ZNF317 | c.1728C>A p.H576Q | Missense Mutation (SNP) | VAF 4/69 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1444282125, COSV56111498; called by muse, mutect2
- SP2 | c.1501C>A p.R501S | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2
- ZMIZ1 | c.785C>A p.A262E | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.103); called by muse, mutect2
- AFF3 | c.1839G>T p.A613= | Silent (SNP) | VAF 5/47 reads (11%) | called by muse, mutect2
- TEX47 | c.543G>T p.L181= | Silent (SNP) | VAF 3/38 reads (8%) | catalogued as COSV51878464; called by muse, mutect2
- USP39 | c.220C>A p.R74= | Silent (SNP) | VAF 5/51 reads (10%) | called by muse, mutect2
- THRB | c.284-12802G>T | Intron (SNP) | VAF 3/50 reads (6%) | called by muse, mutect2
